CCDI case PBCWBN — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/92ca1ba8-ceaa-451c-8de8-35b4d64b2963

Demographics
Sex at birth: male.

Biospecimens (3 samples)
- Sample 0E1NYK: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0E1O0F: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0E1O0N: Tissue type: Tumor; Specimen type: Solid Tissue.
